FM case AD13717 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a418823f-33f0-4154-ad80-460cfa3e333a

Female, 51.9 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
